Somatic mutation profile of tumor specimen TCGA-CR-6484-01A (aliquot TCGA-CR-6484-01A-11D-1870-08) from TCGA case TCGA-CR-6484, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 67.3 years (24,569 days).
Specimen TCGA-CR-6484-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 948f6ee8-016e-4316-aed7-f708c1bb6d7d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-6484-10A (Blood Derived Normal), aliquot TCGA-CR-6484-10A-01D-1870-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/507a3a34-7dac-485f-8d30-17b35ccd3792

The open-access MAF lists 282 somatic variants for this specimen: 208 protein-altering or splice-affecting, 69 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 183, Silent 69, Nonsense Mutation 17, Splice Site 4, Splice Region 2, Intron 2, 5'UTR 1, RNA 1, Nonstop Mutation 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AAAS | c.296C>G p.S99* | Nonsense Mutation (SNP) | VAF 11/33 reads (33%) | catalogued as COSV99266902; called by muse, mutect2, varscan2
- ABHD2 | c.1082-1G>C p.X361_splice | Splice Site (SNP) | VAF 20/107 reads (19%) | catalogued as COSV100756250; called by muse, mutect2, varscan2
- ABI1 | c.926C>T p.S309F | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.996); catalogued as rs752547003, COSV100697829; called by muse, mutect2, varscan2
- ACE2 | c.2082C>G p.I694M | Missense Mutation (SNP) | VAF 37/220 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.02); catalogued as COSV53027164, COSV99382677, COSV99383066; called by muse, mutect2, varscan2
- ADGRA2 | c.1122C>G p.I374M | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100177801; called by muse, varscan2
- AKAP9 | c.9961G>C p.E3321Q (on ENST00000359028; = p.E3297Q on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as rs756245027, COSV62346661; called by muse, mutect2, varscan2
- ALDH8A1 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99664601; called by muse, mutect2
- ANKRD50 | c.1637G>A p.R546K | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV101538920, COSV72385643; called by muse, mutect2
- ANKS4B | c.640G>C p.D214H | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.38); catalogued as COSV100289780; called by muse, mutect2
- APAF1 | c.2425G>A p.D809N (on ENST00000551964 / NM_181861.2; = p.D798N on NM_001160.3) | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.03); catalogued as COSV100452447; called by muse, mutect2, varscan2
- APC | c.4696G>T p.D1566Y | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.733); catalogued as COSV57337256, COSV57371858; called by muse, mutect2, varscan2
- ARFGAP2 | c.969G>C p.E323D | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (1); PolyPhen possibly damaging (0.785); catalogued as COSV100125495; called by muse, mutect2, varscan2
- ARID1B | c.4309G>A p.G1437S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.019); catalogued as rs376207220, COSV51666946; called by muse, mutect2, varscan2
- ARMCX2 | c.1138G>C p.D380H | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100168115; called by muse, mutect2, varscan2
- ASB9 | c.643G>T p.A215S | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV100995455; called by muse, mutect2, varscan2
- ATF7IP | c.1708C>T p.R570C | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.035); catalogued as rs751386917, COSV53773040; called by muse, mutect2, varscan2
- ATG13 | c.978G>C p.E326D (on ENST00000359513 / NM_001346321.1; = p.E289D on NM_014741.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as COSV100365655; called by muse, mutect2, varscan2
- ATL2 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.039); catalogued as COSV100184544; called by muse, mutect2, varscan2
- ATP2B4 | c.3355C>G p.Q1119E | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100397386; called by muse, mutect2, varscan2
- BCAN | c.772G>C p.E258Q | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV100228019, COSV61255373; called by muse, mutect2, varscan2
- BSX | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV100545194; called by muse, mutect2, varscan2
- BTN1A1 | c.635C>G p.S212C | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99764310; called by muse, mutect2, varscan2
- C19orf44 | c.962C>G p.S321* | Nonsense Mutation (SNP) | VAF 12/144 reads (8%) | catalogued as COSV99685062; called by muse, mutect2
- CCM2 | c.826G>A p.V276M | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99347689; called by muse, mutect2
- CDK13 | c.2317G>C p.D773H | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99475363; called by muse, mutect2, varscan2
- CELF3 | c.526G>C p.E176Q | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.178); catalogued as COSV99310198; called by muse, mutect2, varscan2
- CEP162 | c.1432G>C p.E478Q | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.466); catalogued as COSV100002632; called by muse, mutect2
- CHRNA6 | c.562C>G p.L188V | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99373164; called by muse, mutect2
- CIC | c.3670G>C p.E1224Q | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.099); catalogued as COSV99359363; called by muse, mutect2
- CNOT11 | c.591C>G p.F197L | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (0.8); PolyPhen benign (0.061); catalogued as COSV99179246; called by muse, mutect2, varscan2
- CNTN4 | c.598G>A p.V200M | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.38); catalogued as rs377048968; called by muse, mutect2, varscan2
- CNTNAP4 | c.3097G>A p.G1033S | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.231); catalogued as rs1200751731; called by muse, mutect2
- COL1A2 | c.3537G>T p.W1179C | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99799269; called by muse, mutect2
- CPEB1 | c.652G>C p.D218H (on ENST00000617958; = p.D158H on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.875); catalogued as COSV99917587; called by muse, mutect2
- CPXCR1 | c.573G>C p.E191D | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV99342100; called by muse, mutect2, varscan2
- CSE1L | c.1192G>C p.E398Q | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99521955; called by muse, mutect2
- CSRP1 | c.24G>C p.K8N | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100384426; called by muse, mutect2, varscan2
- DDR2 | c.1546G>C p.E516Q | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.122); catalogued as COSV100906425; called by muse, mutect2
- DDX21 | c.1795G>A p.E599K | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.097); catalogued as COSV100826506; called by muse, mutect2, varscan2
- DELE1 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.333); catalogued as rs372014031; called by muse, mutect2, varscan2
- DGCR8 | c.2068A>G p.N690D | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.704); catalogued as COSV99349924; called by muse, mutect2
- DHODH | c.893C>G p.S298C | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); catalogued as COSV54661290; called by muse, mutect2, varscan2
- DHX29 | c.634G>C p.E212Q | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.046); catalogued as COSV99287176; called by muse, mutect2, varscan2
- DPCD | c.276C>G p.I92M | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as COSV100924249; called by muse, mutect2, varscan2
- DRC7 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.901); catalogued as rs116219187, COSV100395500; called by mutect2, varscan2
- DUSP26 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.953); catalogued as rs753004086, COSV99823387; called by muse, mutect2, varscan2
- EPN1 | c.1216G>C p.D406H (on ENST00000270460 / NM_001321263.1; = p.D380H on NM_013333.3) | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV50036220, COSV99321796; called by muse, mutect2, varscan2
- FAM234A | c.1162G>C p.E388Q | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV99395744; called by muse, mutect2, varscan2
- FAM91A1 | c.1284G>C p.Q428H | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.465); catalogued as COSV100593520; called by muse, varscan2
- FBLIM1 | c.794C>T p.S265F | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); catalogued as COSV100181669; called by muse, mutect2
- FCGR2C | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV100912671; called by muse, mutect2
- FDX1 | c.326C>G p.T109S | Missense Mutation (SNP) | VAF 31/195 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as COSV99501819; called by muse, mutect2, varscan2
- FLNA | c.6916G>T p.E2306* (on ENST00000369850 / NM_001110556.2; = p.E2298* on NM_001456.3) | Nonsense Mutation (SNP) | VAF 7/43 reads (16%) | catalogued as COSV100774517; called by muse, mutect2, varscan2
- FMO2 | c.113G>A p.G38E | Missense Mutation (SNP) | VAF 16/175 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV52950169; called by muse, mutect2
- FOXK1 | c.1702G>C p.E568Q | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.863); catalogued as COSV100194928; called by muse, mutect2
- GABRB2 | c.1506C>G p.F502L (on ENST00000274547; = p.F464L on NM_000813.3) | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50953623, COSV99195865; called by muse, mutect2, varscan2
- GALNT14 | c.1629G>A p.M543I | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.021); catalogued as rs756871233, COSV100204419; called by muse, mutect2, varscan2
- GIMAP8 | c.215C>T p.S72L | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as rs780657422, COSV100217466; called by muse, mutect2, varscan2
- GLDC | c.850C>T p.H284Y | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV100394011, COSV58682499; called by muse, mutect2, varscan2
- GOLGA6A | c.569C>G p.S190W | Missense Mutation (SNP) | VAF 15/191 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs757384467, COSV99297101; called by muse, mutect2
- GPATCH1 | c.1077G>C p.K359N | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV99403916; called by muse, mutect2
- H2BC7 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.812); catalogued as COSV100587227, COSV61911476, COSV61912249; called by muse, mutect2
- HECTD1 | c.1455G>C p.W485C | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV101237346; called by muse, mutect2, varscan2
- HELZ | c.5252G>C p.R1751T | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV100698626; called by muse, mutect2, varscan2
- HIPK3 | c.1789G>A p.A597T | Missense Mutation (SNP) | VAF 42/392 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100305627; called by muse, varscan2
- HMCN1 | c.11824G>C p.D3942H | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV99627404; called by muse, mutect2
- HSPA1L | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.53); catalogued as COSV100989367; called by muse, mutect2, varscan2
- HUWE1 | c.7199G>A p.R2400Q | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.921); catalogued as COSV53340179; called by muse, mutect2, varscan2
- IFIH1 | c.628G>C p.E210Q | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.109); catalogued as COSV99718566; called by muse, mutect2
- IFNLR1 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs772933526, COSV59527674; called by muse, mutect2, varscan2
- IHO1 | c.994G>C p.E332Q | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.563); catalogued as COSV99606013; called by muse, mutect2, varscan2
- INPP5F | c.808G>C p.D270H | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV100740077; called by muse, mutect2
- IST1 | c.1073C>G p.S358* (on ENST00000535424 / NM_001270976.1; = p.Q344E on NM_014761.4) | Nonsense Mutation (SNP) | VAF 13/319 reads (4%) | catalogued as COSV100324618, COSV58662049; called by muse, mutect2
- KCNA6 | c.301C>T p.Q101* | Nonsense Mutation (SNP) | VAF 19/92 reads (21%) | catalogued as rs1350682349, COSV99768530; called by muse, mutect2, varscan2
- KCNH3 | c.1517G>A p.R506H | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99235049; called by muse, mutect2, varscan2
- KCNK16 | c.633C>A p.S211R | Missense Mutation (SNP) | VAF 39/307 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1320798337, COSV100949160; called by muse, mutect2, varscan2
- KHDC4 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.43); catalogued as COSV100850789; called by muse, mutect2, varscan2
- KIF14 | c.4718C>G p.S1573C | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV100950779; called by muse, mutect2, varscan2
- KIF4B | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.588); catalogued as rs1390704156, COSV70530133; called by muse, mutect2, varscan2
- KIFC1 | c.515G>C p.R172T | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.03); catalogued as COSV100997095; called by muse, mutect2, varscan2
- KMT2D | c.5791C>A p.P1931T | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV56425008, COSV99979932; called by muse, mutect2, varscan2
- KPNA6 | c.209C>G p.S70C | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); catalogued as COSV101012465; called by muse, mutect2
- KRT12 | c.1096-1G>A p.X366_splice | Splice Site (SNP) | VAF 4/16 reads (25%) | catalogued as COSV99288891; called by muse, mutect2, varscan2
- KRTAP5-3 | c.416C>G p.S139* | Nonsense Mutation (SNP) | VAF 27/230 reads (12%) | catalogued as COSV101294500, COSV68790649; called by muse, mutect2, varscan2
- LAMA4 | c.196-1G>A p.X66_splice | Splice Site (SNP) | VAF 10/54 reads (19%) | catalogued as COSV99683678; called by muse, mutect2, varscan2
- LIMCH1 | c.1447C>T p.P483S | Missense Mutation (SNP) | VAF 40/401 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV100573679; called by muse, mutect2
- LMBRD1 | c.1658G>T p.S553I (on ENST00000649011; = p.S531I on NM_018368.4) | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100992533; called by muse, mutect2
- LRG1 | c.275C>G p.S92C | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as COSV100014777; called by muse, mutect2, varscan2
- LRP6 | c.4841G>C p.*1614Sext*7 | Nonstop Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as COSV99742966; called by muse, mutect2
- LRRC55 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.474); catalogued as COSV101546727; called by muse, mutect2, varscan2
- LURAP1L | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100070667, COSV59983756; called by muse, mutect2, varscan2
- MADD | c.37G>C p.D13H | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100211310, COSV60628178; called by muse, mutect2, varscan2
- MAP3K12 | c.1891G>A p.D631N | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.015); catalogued as COSV99913154; called by muse, mutect2, varscan2
- MCOLN3 | c.1135A>G p.T379A | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as COSV100352679, COSV62014811; called by muse, mutect2, varscan2
- MDH1 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.858); catalogued as COSV99250947; called by muse, mutect2, varscan2
- METTL9 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.863); catalogued as COSV100820539; called by muse, mutect2
- MGMT | c.497G>A p.R166K (on ENST00000306010; = p.R135K on NM_002412.5) | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.118); catalogued as rs762165032, COSV100022824; called by muse, mutect2, varscan2
- MIA3 | c.2870C>T p.S957L | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100719400; called by muse, mutect2, varscan2
- MICU2 | c.393C>T p.D131= | Splice Region (SNP) | VAF 17/42 reads (40%) | catalogued as COSV101212427; called by muse, mutect2, varscan2
- MYL6B | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); catalogued as COSV99255151; called by muse, mutect2, varscan2
- MYL6B | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 34/260 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as rs950965377, COSV99255152; called by muse, mutect2, varscan2
- MYO1B | c.628C>T p.Q210* | Nonsense Mutation (SNP) | VAF 23/182 reads (13%) | catalogued as COSV100268948; called by muse, mutect2, varscan2
- MYOCD | c.1478C>T p.T493M | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs774155323, COSV58508200; called by muse, mutect2, varscan2
- NAA35 | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV100863317; called by muse, mutect2, varscan2
- NCBP1 | c.986G>C p.R329T | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV100912575; called by muse, mutect2, varscan2
- NES | c.2525C>G p.S842C | Missense Mutation (SNP) | VAF 13/161 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.06); catalogued as COSV100957833; called by muse, mutect2
- NF2 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD144435, COSV100098061; called by muse, mutect2, varscan2
- NLGN4X | c.819C>G p.F273L | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99321102; called by muse, mutect2, varscan2
- NMNAT1 | c.105G>C p.M35I | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.111); catalogued as COSV101020403, COSV101020473; called by muse, mutect2, varscan2
- NUP153 | c.1895C>G p.T632R | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.333); catalogued as COSV100020134; called by muse, mutect2, varscan2
- NUP214 | c.1102G>T p.D368Y | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100845229; called by muse, mutect2, varscan2
- NXNL1 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs757310322, COSV100111923; called by muse, mutect2, varscan2
- OFD1 | c.1745A>T p.N582I | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100406849; called by muse, mutect2, varscan2
- OR2H1 | c.839C>G p.T280S | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV101009818; called by muse, mutect2, varscan2
- OR2M7 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as rs746504653, COSV58739412; called by muse, mutect2, varscan2
- OR2T12 | c.129G>T p.M43I | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV100527686, COSV58778387; called by muse, mutect2, varscan2
- OR6A2 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.071); catalogued as COSV100215704; called by muse, mutect2, varscan2
- OR8K5 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV100537193; called by muse, mutect2, varscan2
- OSGIN2 | c.1060C>T p.H354Y | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV52411060; called by muse, mutect2, varscan2
- PAK6 | c.1741G>T p.E581* | Nonsense Mutation (SNP) | VAF 7/56 reads (13%) | catalogued as COSV99544398; called by muse, mutect2, varscan2
- PAX3 | c.1243C>G p.L415V | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.859); catalogued as COSV100399450; called by muse, mutect2, varscan2
- PCDH11X | c.3031C>G p.P1011A | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.034); catalogued as COSV100010789; called by muse, mutect2, varscan2
- PCLO | c.14513A>G p.H4838R | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV100430469; called by muse, mutect2, varscan2
- PDIA6 | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99694566; called by muse, mutect2, varscan2
- PFAS | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100118878; called by muse, mutect2, varscan2
- PFDN2 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.95); catalogued as rs778594322, COSV100919660; called by muse, mutect2, varscan2
- PGBD1 | c.2240C>T p.S747L | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs147237521; called by muse, mutect2, varscan2
- PITPNB | c.202G>C p.V68L | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.573); catalogued as COSV100086722; called by muse, mutect2, varscan2
- PKD2L1 | c.2368G>C p.E790Q | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.035); catalogued as COSV100559349; called by muse, mutect2, varscan2
- PLEKHG3 | c.36C>A p.S12R | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as COSV99906476; called by muse, mutect2
- PNN | c.1700G>C p.R567T | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.288); catalogued as COSV99397140; called by muse, mutect2
- POLD1 | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.194); catalogued as rs748471297, COSV101486820; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLR3A | c.3459C>G p.I1153M | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV64930172; called by muse, mutect2, varscan2
- PPM1A | c.30G>A p.M10I | Missense Mutation (SNP) | VAF 15/197 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs747884798, COSV100348848, COSV57788747; called by muse, mutect2
- PRKCH | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 41/335 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs757643373, COSV100273136; called by muse, mutect2, varscan2
- PRSS1 | c.695T>G p.V232G | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100297906; called by muse, varscan2
- PRSS53 | c.1427G>A p.G476D | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.802); catalogued as COSV54923014, COSV99762192; called by muse, mutect2
- PSD4 | c.1884C>G p.F628L | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55528673; called by muse, mutect2
- PTPRA | c.1716C>G p.F572L | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.094); catalogued as COSV99399578; called by muse, mutect2
- PYGO1 | c.910C>T p.Q304* | Nonsense Mutation (SNP) | VAF 51/406 reads (13%) | catalogued as COSV100114585; called by muse, mutect2, varscan2
- QTRT2 | c.793G>C p.E265Q | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.3); catalogued as COSV99846865; called by muse, mutect2, varscan2
- R3HDM1 | c.574T>A p.F192I | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99926032; called by muse, mutect2, varscan2
- RABEPK | c.475G>C p.E159Q | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.877); catalogued as COSV99413338; called by muse, mutect2, varscan2
- RAD50 | c.3278G>A p.R1093Q | Missense Mutation (SNP) | VAF 32/234 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.068); catalogued as rs781612348, COSV54750810; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RC3H1 | c.634G>C p.E212Q | Missense Mutation (SNP) | VAF 11/168 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51203541, COSV99281242; called by muse, mutect2
- RGS19 | c.357C>G p.F119L | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100180671, COSV58657470; called by muse, mutect2, varscan2
- RGS22 | c.3667C>G p.L1223V | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100693151, COSV62660218; called by mutect2, varscan2
- RHEBL1 | c.54G>A p.G18= | Splice Region (SNP) | VAF 27/102 reads (26%) | catalogued as COSV99987977; called by muse, mutect2, varscan2
- RIN2 | c.2617G>C p.E873Q (on ENST00000255006 / NM_001242581.1; = p.E824Q on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.051); catalogued as rs986555562, COSV99656889; called by muse, mutect2
- RNF151 | c.44A>G p.D15G | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV100364394; called by muse, mutect2, varscan2
- ROCK2 | c.877C>A p.P293T | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99837239; called by muse, mutect2
- RPS6KC1 | c.1877C>A p.S626* | Nonsense Mutation (SNP) | VAF 4/47 reads (9%) | catalogued as COSV100873846; called by muse, mutect2
- RRBP1 | c.1996G>A p.E666K (on ENST00000377813 / NM_001365613.2; = p.E233K on NM_004587.3) | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1401642343, COSV55696990; called by muse, mutect2, varscan2
- SEC14L4 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.219); catalogued as rs1283887960, COSV55400368; called by muse, mutect2, varscan2
- SFI1 | c.285C>G p.F95L | Missense Mutation (SNP) | VAF 5/110 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV101192056; called by muse, mutect2
- SFN | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (1); catalogued as COSV100212775, COSV59433995; called by muse, mutect2, varscan2
- SIGMAR1 | c.600C>G p.F200L | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.183); catalogued as COSV99449498; called by muse, mutect2, varscan2
- SLC12A4 | c.966C>G p.I322M | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.125); catalogued as COSV100311636; called by muse, mutect2, varscan2
- SLC5A7 | c.1324G>T p.G442C | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99886536; called by muse, mutect2, varscan2
- SLC6A4 | c.1751C>A p.S584* | Nonsense Mutation (SNP) | VAF 12/128 reads (9%) | catalogued as COSV99911319; called by muse, mutect2
- SMAD2 | c.981G>C p.M327I | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100053567; called by muse, mutect2
- SMG5 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 38/336 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as COSV62437365; called by muse, mutect2, varscan2
- SPEF2 | c.5018C>G p.S1673* | Nonsense Mutation (SNP) | VAF 5/36 reads (14%) | catalogued as COSV100288708, COSV100288912; called by muse, mutect2, varscan2
- SPEN | c.6418G>C p.D2140H | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV101005123; called by muse, mutect2, varscan2
- SPPL2C | c.1837G>A p.E613K | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.326); catalogued as COSV100234005; called by muse, mutect2, varscan2
- SRRM3 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV58388703; called by muse, mutect2, varscan2
- STYXL1 | c.319C>T p.Q107* | Nonsense Mutation (SNP) | VAF 24/168 reads (14%) | catalogued as COSV99951342; called by muse, mutect2, varscan2
- TAF6 | c.1546C>T p.P516S | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.968); catalogued as rs1164745863, COSV100612676; called by muse, mutect2
- TASOR2 | c.3635C>A p.S1212Y | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as COSV100050299; called by muse, mutect2, varscan2
- TASOR2 | c.3721C>T p.H1241Y | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV60167548; called by muse, mutect2, varscan2
- TBC1D8 | c.1139G>A p.R380Q | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as rs778237994, COSV100964388, COSV65213869; called by muse, mutect2, varscan2
- TBL1X | c.1670G>A p.R557Q | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as rs777898197, COSV99482401; called by muse, mutect2, varscan2
- TMEM107 | c.420C>G p.F140L (on ENST00000437139 / NM_183065.4; = p.F146L on NM_032354.5) | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV100328721; called by muse, mutect2, varscan2
- TMTC2 | c.2293G>C p.E765Q | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100337754; called by muse, mutect2
- TNNT3 | c.678C>G p.F226L (on ENST00000397301 / NM_001367846.1; = p.F215L on NM_006757.4) | Missense Mutation (SNP) | VAF 35/193 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV53485391, COSV99548130; called by muse, mutect2, varscan2
- TNS4 | c.2096C>T p.S699L | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.895); catalogued as rs372382060; called by muse, mutect2, varscan2
- TRIM15 | c.370C>G p.Q124E | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.036); catalogued as COSV100938804, COSV64988985; called by muse, mutect2, varscan2
- TTN | c.85478C>G p.S28493* (on ENST00000591111; = p.S21069* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 7/46 reads (15%) | catalogued as COSV100604980; called by muse, mutect2, varscan2
- TXNL4B | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV99194261; called by muse, mutect2, varscan2
- UCK2 | c.550C>G p.Q184E | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100902914; called by muse, mutect2
- UPF1 | c.99C>G p.F33L | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV53194738, COSV99439264; called by muse, mutect2, varscan2
- USF1 | c.248G>A p.G83D | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as COSV99230949; called by muse, mutect2, varscan2
- UTRN | c.2131C>G p.Q711E | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.08); catalogued as rs925963849, COSV100839795; called by muse, mutect2, varscan2
- VCPIP1 | c.1387G>C p.D463H | Missense Mutation (SNP) | VAF 34/289 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV100125493; called by muse, mutect2, varscan2
- WDFY1 | c.30G>C p.Q10H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.205); catalogued as COSV99239344; called by muse, mutect2, varscan2
- WDR48 | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV100176508; called by muse, mutect2, varscan2
- WDR62 | c.4036C>G p.P1346A | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV54334856, COSV99543496; called by muse, mutect2, varscan2
- WNK3 | c.1582C>G p.L528V | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as COSV100671150; called by muse, mutect2, varscan2
- WNT1 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV99525269; called by muse, mutect2, varscan2
- YAE1 | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV99784913; called by muse, mutect2
- ZC3H4 | c.2704G>A p.E902K | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.69); PolyPhen benign (0.012); catalogued as rs781277526, COSV53410267; called by muse, mutect2, varscan2
- ZC3H8 | c.436C>T p.R146* | Nonsense Mutation (SNP) | VAF 10/85 reads (12%) | catalogued as rs1422939244, COSV99735297; called by muse, mutect2
- ZCCHC4 | c.850G>C p.E284Q | Missense Mutation (SNP) | VAF 32/208 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.577); catalogued as COSV100255119; called by muse, mutect2, varscan2
- ZNF300 | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs1413638727, COSV99199844; called by muse, mutect2, varscan2
- ZNF429 | c.1789G>C p.E597Q | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV100641847; called by muse, mutect2
- ZNF513 | c.1049G>A p.G350E | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.79); PolyPhen benign (0.055); catalogued as COSV99277456; called by muse, mutect2, varscan2
- ZNF536 | c.2972C>G p.S991W | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV100835024, COSV62835611; called by muse, mutect2, varscan2
- ZNF574 | c.1518G>C p.K506N | Missense Mutation (SNP) | VAF 34/271 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV99725991; called by muse, mutect2, varscan2
- ZNF681 | c.1220C>G p.S407* | Nonsense Mutation (SNP) | VAF 8/85 reads (9%) | catalogued as COSV101267437, COSV68075592; called by muse, mutect2, varscan2
- ZNF74 | c.220G>C p.E74Q | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1209539068, COSV62620078; called by muse, mutect2
- ZP4 | c.1538C>G p.S513C | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as COSV100850650, COSV63913697; called by muse, mutect2, varscan2
- CMYA5 | c.11092A>C p.M3698L | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2
- GAGE2E | c.249G>C p.Q83H | Missense Mutation (SNP) | VAF 29/1038 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.203); called by muse, mutect2
- LDLRAD3 | c.841G>C p.D281H | Missense Mutation (SNP) | VAF 38/1580 reads (2%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.67); called by muse, mutect2
- PDE1A | c.1565-1G>A p.X522_splice | Splice Site (SNP) | VAF 4/42 reads (10%) | called by mutect2, varscan2
- R3HDML | c.103del p.Q35Sfs*10 | Frame Shift Del (DEL) | VAF 11/76 reads (14%) | called by mutect2, pindel, varscan2
- XRCC4 | c.71G>C p.W24S | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AFAP1L2 | c.2232G>C p.L744= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV100412390; called by muse, mutect2, varscan2
- ARID3C | c.1238G>A p.*413= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as COSV52407387, COSV99426830; called by muse, mutect2
- ARMC9 | c.1578G>A p.L526= | Silent (SNP) | VAF 18/183 reads (10%) | catalogued as rs1357733284, COSV100589651; called by muse, mutect2, varscan2
- ATG9B | c.2316C>T p.F772= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs574780705, COSV52488396; called by muse, mutect2, varscan2
- ATP6V1B1 | c.834C>T p.F278= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as COSV99313968; called by muse, mutect2, varscan2
- BCL7C | c.264C>T p.I88= | Silent (SNP) | VAF 22/141 reads (16%) | catalogued as COSV99288573; called by muse, mutect2, varscan2
- CANT1 | c.1083C>G p.L361= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV100185228; called by mutect2, varscan2
- CARNS1 | c.1902G>C p.L634= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV100321904; called by muse, mutect2, varscan2
- CCDC58 | c.60C>G p.L20= | Silent (SNP) | VAF 7/75 reads (9%) | catalogued as COSV99360455, COSV99360602; called by muse, mutect2, varscan2
- CHD7 | c.3309C>T p.V1103= | Silent (SNP) | VAF 14/148 reads (9%) | catalogued as COSV101418157; called by muse, mutect2
- COL11A1 | c.4152T>C p.G1384= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV100615951; called by muse, mutect2
- COL22A1 | c.564C>T p.I188= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs750855901, COSV57359043; called by muse, mutect2, varscan2
- COL5A3 | c.4086C>T p.I1362= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV99318553; called by muse, mutect2
- CST9L | c.297G>C p.G99= | Silent (SNP) | VAF 26/276 reads (9%) | catalogued as COSV100980852; called by muse, mutect2
- DCAF4L2 | c.483G>A p.A161= | Silent (SNP) | VAF 41/106 reads (39%) | catalogued as rs1369010251, COSV60480151; called by muse, mutect2, varscan2
- DCDC2B | c.591T>C p.Y197= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as rs367842387; called by muse, mutect2, varscan2
- DIP2B | c.4716G>A p.V1572= | Silent (SNP) | VAF 24/94 reads (26%) | catalogued as COSV99998281; called by muse, varscan2
- DIXDC1 | c.345C>T p.I115= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV100180173; called by muse, mutect2, varscan2
- DOCK6 | c.2979C>G p.L993= | Silent (SNP) | VAF 6/89 reads (7%) | catalogued as COSV99625305; called by muse, mutect2
- EDC3 | c.156C>T p.V52= | Silent (SNP) | VAF 30/212 reads (14%) | catalogued as COSV100165900; called by muse, mutect2, varscan2
- EDRF1 | c.2187C>G p.L729= (on ENST00000356792 / NM_001202438.2; = p.L695= on NM_015608.2) | Silent (SNP) | VAF 34/152 reads (22%) | catalogued as COSV100523387; called by muse, mutect2, varscan2
- ELMO1 | c.1113C>T p.F371= | Silent (SNP) | VAF 18/188 reads (10%) | catalogued as COSV100164012; called by muse, mutect2
- EML1 | c.765G>A p.V255= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV99214811; called by muse, mutect2, varscan2
- FAM111A | c.1230G>A p.V410= | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as rs1209875025, COSV100659356; called by muse, mutect2, varscan2
- FBXO10 | c.2805G>A p.T935= | Silent (SNP) | VAF 17/148 reads (11%) | catalogued as rs1030794098, COSV99446495; called by muse, mutect2, varscan2
- FCF1 | c.465C>T p.Y155= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as rs1243134667, COSV62043867; called by muse, mutect2, varscan2
- GAL3ST3 | c.810C>T p.R270= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as rs1213580258, COSV61749748; called by muse, mutect2, varscan2
- GPR63 | c.592C>T p.L198= | Silent (SNP) | VAF 7/128 reads (5%) | catalogued as COSV100013258, COSV57741087; called by muse, mutect2
- GPS2 | c.732C>G p.L244= | Silent (SNP) | VAF 17/99 reads (17%) | catalogued as rs769049828, COSV100222865; called by muse, mutect2, varscan2
- HIRA | c.606G>A p.R202= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as rs1268317243, COSV99600147; called by muse, mutect2
- IFT172 | c.1506C>T p.F502= | Silent (SNP) | VAF 17/188 reads (9%) | catalogued as rs776207701, COSV99562166; called by muse, mutect2, varscan2
- IL4I1 | c.582C>G p.L194= | Silent (SNP) | VAF 21/152 reads (14%) | catalogued as COSV99680551; called by muse, mutect2, varscan2
- ITPRIPL2 | c.405C>A p.R135= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as COSV101198169; called by muse, mutect2
- KCNJ5 | c.579C>G p.P193= | Silent (SNP) | VAF 15/121 reads (12%) | catalogued as COSV100610631; called by muse, mutect2, varscan2
- LAMC2 | c.3084G>A p.L1028= | Silent (SNP) | VAF 21/152 reads (14%) | catalogued as COSV99917313; called by muse, mutect2, varscan2
- LILRB5 | c.1089C>T p.P363= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV100300246, COSV100300786, COSV60254150; called by muse, mutect2, varscan2
- LMNB2 | c.372G>C p.L124= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV100322075, COSV100322531; called by muse, mutect2, varscan2
- LRCH1 | c.1788C>T p.V596= | Silent (SNP) | VAF 20/153 reads (13%) | catalogued as COSV100243506; called by muse, mutect2, varscan2
- LRIT2 | c.1494C>T p.R498= | Silent (SNP) | VAF 19/89 reads (21%) | catalogued as rs140185624; called by muse, mutect2, varscan2
- MEX3B | c.330C>G p.V110= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV100313975; called by muse, mutect2, varscan2
- MYL6B | c.339G>A p.K113= | Silent (SNP) | VAF 23/146 reads (16%) | catalogued as COSV52879161, COSV99255155; called by muse, mutect2, varscan2
- NLRP13 | c.1338G>A p.Q446= | Silent (SNP) | VAF 15/131 reads (11%) | catalogued as COSV100738153; called by muse, mutect2, varscan2
- NOTCH2 | c.5463G>C p.V1821= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV56686712; called by muse, mutect2, varscan2
- NR4A1 | c.768G>C p.R256= | Silent (SNP) | VAF 15/154 reads (10%) | catalogued as COSV54480229, COSV99671205; called by muse, mutect2
- NT5C3A | c.150C>T p.F50= (on ENST00000610140 / NM_001374335.1; = p.F16= on NM_016489.13) | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as COSV99641051; called by muse, mutect2
- OIP5 | c.150C>G p.L50= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as COSV99530833; called by muse, mutect2, varscan2
- PAQR9 | c.1011C>G p.L337= | Silent (SNP) | VAF 20/167 reads (12%) | catalogued as COSV100503766; called by muse, mutect2, varscan2
- PDCD2L | c.930C>G p.L310= | Silent (SNP) | VAF 15/125 reads (12%) | catalogued as COSV55825909, COSV99874962; called by muse, mutect2, varscan2
- PIDD1 | c.2316C>G p.L772= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV100204169; called by muse, mutect2, varscan2
- PPFIA1 | c.3072G>C p.L1024= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV99557246; called by muse, mutect2, varscan2
- PSMD4 | c.51G>A p.R17= | Silent (SNP) | VAF 12/121 reads (10%) | catalogued as COSV100924659, COSV64393368; called by muse, mutect2, varscan2
- PTX3 | c.627C>T p.A209= | Silent (SNP) | VAF 14/108 reads (13%) | catalogued as COSV99904842; called by muse, mutect2, varscan2
- RASL12 | c.294C>T p.Y98= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV99584867; called by muse, mutect2, varscan2
- RGS14 | c.660G>A p.P220= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs770834079, COSV101281713; called by muse, mutect2, varscan2
- RHOH | c.282G>A p.L94= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV101110465; called by muse, mutect2, varscan2
- RNF24 | c.66C>T p.L22= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV100270849; called by muse, mutect2
- SACS | c.4023C>G p.L1341= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV66538200; called by muse, mutect2, varscan2
- SAMD9 | c.3513A>G p.E1171= | Silent (SNP) | VAF 27/206 reads (13%) | catalogued as COSV101180186; called by muse, mutect2, varscan2
- SAV1 | c.966G>A p.L322= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV100220711; called by muse, mutect2, varscan2
- SPAST | c.183C>T p.F61= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as COSV100188460, COSV59515052; called by muse, mutect2
- SRMS | c.1206C>G p.V402= | Silent (SNP) | VAF 18/207 reads (9%) | catalogued as COSV99420441; called by muse, mutect2
- TFR2 | c.870C>T p.F290= | Silent (SNP) | VAF 24/125 reads (19%) | catalogued as COSV56154971; called by muse, mutect2, varscan2
- TLN2 | c.1644T>C p.S548= | Silent (SNP) | VAF 8/102 reads (8%) | catalogued as COSV100168667; called by muse, mutect2
- TM4SF18 | c.600C>T p.I200= | Silent (SNP) | VAF 14/139 reads (10%) | catalogued as COSV99937831, COSV99937878; called by muse, mutect2, varscan2
- TMEM150B | c.657C>T p.L219= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV100442287; called by muse, mutect2
- TMEM203 | c.189C>T p.F63= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV100411112; called by muse, mutect2
- VWA8 | c.2289G>A p.V763= | Silent (SNP) | VAF 16/166 reads (10%) | catalogued as COSV99863880; called by muse, mutect2
- ZNF232 | c.324G>A p.L108= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as COSV51503141; called by muse, mutect2, varscan2
- ZNF451 | c.2707C>T p.L903= | Silent (SNP) | VAF 18/141 reads (13%) | catalogued as COSV100674831; called by muse, mutect2, varscan2
- C8orf31 | n.379C>G | RNA (SNP) | VAF 11/149 reads (7%) | called by muse, mutect2
- PRR12 | c.52-328G>C | Intron (SNP) | VAF 7/26 reads (27%) | catalogued as COSV101330631; called by muse, mutect2, varscan2
- RN7SL484P | chr15:99792167 G>T | 3'Flank (SNP) | VAF 33/165 reads (20%) | catalogued as rs377235220; called by muse, mutect2, varscan2
- SDHA | c.-1C>T | 5'UTR (SNP) | VAF 4/24 reads (17%) | catalogued as rs560932680, COSV99371495; ClinVar: likely benign / uncertain significance; called by muse, varscan2
- ZNF304 | c.161-755C>T | Intron (SNP) | VAF 7/57 reads (12%) | catalogued as COSV99988558; called by muse, mutect2, varscan2
